CCDI case PBCNUG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/c2810cb7-3cfb-4c55-a220-a1e6a7a4ecd4

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Ganglioneuroma: ICD-O-3 morphology code: 9490/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 8.0 years (2,927 days).

Biospecimens (2 samples)
- Sample 0DWHZ7: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DWI1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
